Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7915, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7915-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* Preliminary *

Patient Name:

Med. Rec. #:

DOB/Gender:

Location:

Soc. Sec. #:

Physician(s):

Path No.:

Client:

Collected:

Received:

Reported:

Hosp #:

F

Pre-Operative/Clinical History

Nonfunctioning left kidney

Specimen(s) Received

A: TORSSED APPENDAGE EPIPLOICA

B: PERIHILAR RENAL LYMPH NODE

C: LEFT KIDNEY

Gross Description

Specimen A, received in formalin labeled torsed appendage epiploica, consists of a hemorrhagic firm portion of adipose tissue measuring 2.8 x 1.5 x 0.5 cm. The cut surface is tan-brown. Representative sections are submitted.

Specimen B, received in formalin labeled perihilar renal lymph node, consists of a 1.7 x 1.3 x 0.8 cm portion of a lymph node. The cut surface is homogenous tan-pink. The node is sectioned and entirely submitted labeled

Specimen C, received fresh from the OR labeled left kidney, consists of the following:

Procedure/specimen type: Radical nephrectomy.

Specimen laterality: Left.

Description of specimen: The 726 gm kidney with associated perinephric fat measures overall 19.0 x 14.0 x 7.0 cm. Gerota's fascia is hemorrhagic with fibrous adhesions. Gerota's fascia is fibrotic and thickened measuring up to 0.5 cm. The perinephric fat is firm and lobulated measuring up to 2.0 cm in thickness. Blue ink is applied to Gerota's fascia and the mass grossly appears to abut the fascia. The attached segment of ureter measures 4.0 cm in length with an internal diameter of 0.3 cm and is grossly unremarkable and not involved by the tumor.

The kidney measures 12.0 x 6.5 x 5.5 cm. The kidney is surrounded by a large cystic hemorrhagic mass containing blood clot. The mass is attached to the kidney and grossly involves the renal parenchyma superiorly. Sections show a soft tan expansile solid area within the cystic mass abutting the surface of the kidney and slightly compressing the renal parenchyma.

The renal pelvis is slightly displaced. The corticomedullary junction within the superior pole of the kidney is pale white-pink and compressed. Within the superior pole of the kidney is a portion of attached adrenal gland measuring 3.0 x 3.0 x 0.3 cm. The adrenal parenchyma shows thin brown medulla with focally thickened golden yellow cortex. The portion of adrenal gland is markedly adherent to the surface of the kidney and gross involvement by tumor cannot be definitively determined.

[page 2 of 4]
- Adrenal gland:** Also received within the specimen container is a separate portion of adrenal gland measuring 5.0 x 2.2 x 1.5 cm and weighing 8 gm. The cut surface shows thin golden yellow cortices with brown medulla. The adrenal gland grossly does not appear to be involved by the tumor.
- Tumor site:** Supracortical, with the solid component predominantly involving the superior pole of the kidney and the cystic component involving the remainder of the external kidney.
- Tumor size:** The cystic component measures 19 cm in greatest dimension and the solid component measures 5.0 cm in greatest dimension.
- Tumor description:** The cystic mass involves the renal capsule with possible focal extension into the renal parenchyma. Within the cystic mass is a moderate amount of blood clot. The luminal surface of the mass is focally nodular. The cystic mass wall ranges from 0.1 cm to 0.6 cm in thickness. A representative section is submitted for frozen section [REDACTED]
- Focality:** Unifocal.
- Extent of invasion:** The tumor involves the renal capsule with foci suspicious for infiltration into renal parenchyma.
- Renal vessel involvement:** Absent.
- Renal hilum:** Uninvolved by tumor.
- Perinephric lymph nodes:** A single perinephric lymph node measuring 2.0 x 1.3 x 1.0 cm which grossly is uninvolved by the tumor is present.
- Renal parenchymal lesions:** None identified.

Gross photos are taken.

Representative sections are submitted as follows:

- (C1FS) Remainder of the frozen tissue
- (C2) Ureteral margin, en face
- (C3) Renal artery and vein margin, en face
- (C4, 5) Gerota's fascia, perpendicular sections showing proximity of tumor
- (C6, 7) Adrenal gland and underlying tumor
- (C8) Separate portion of adrenal gland
- (C9) Renal hilum
- (C10) Renal lymph node, sectioned
- (C11-18) Kidney with adjacent tumor with questionable areas of renal parenchymal involvement in (C11-13)
- (C19-25) Cystic mass wall
- [REDACTED]
- (C26) Renal pelvic mucosa
- (C27) Superior calyceal mucosa
- (C28) Inferior calyceal mucosa
- (C29) Superior renal parenchyma
- (C30) Inferior renal parenchyma.
- [REDACTED]

Intraoperative Consultation

Specimen C, frozen section diagnosis of "carcinoma" is rendered by [REDACTED]

[page 3 of 4]
Microscopic Description**Summary of Pathologic Findings
Renal Carcinoma**

Operative procedure: Radical nephrectomy.

Tumor size: The cystic component of the tumor is 19.0 cm in greatest dimension with a solid component of 5.0 cm in greatest dimension.

Laterality and focality: Left and unifocal.

Histologic type: Papillary renal cell carcinoma.

Sarcomatoid features: Absent.

Histologic grade: Fuhrman 3/4.

Extent of invasion: Extracapsular invasion into the perinephric tissue, not beyond Gerota's fascia.

Lymph/vascular invasion: Absent.

Margins:

Radical nephrectomy margins:

Renal vein margin: Negative.

Gerota's fascial margin: Negative.

Ureteral margin: Negative.

Adrenal gland: Not involved.

Regional lymph nodes:

Number of nodes examined: 2. (includes specimen A)

Number of nodes positive for tumor: 0.

Special studies: A panel of immunohistochemical stains is performed to delineate the immunophenotype of this tumor. The following staining pattern is observed:

CD10	Negative
P504S	Positive
Vimentin	Positive
CK7	Negative
Low molecular weight keratin	Positive
Mart-1	Negative
HMB-45	Negative
CD117	Negative
N-cadherin	Positive
TFE3	-----

pTNM stage: pT2b, pN0.

The submitted epiploica (B) demonstrates infarction consistent with the clinical impression of torsion. There is no evidence of tumor.

[page 4 of 4]
A perihilar lymph node (A) is submitted which demonstrates follicular hyperplasia as does the node attached to the kidney.

Pathologic findings in nonneoplastic kidney: Interstitial nephritis.

Diagnosis

TORSED APPENDAGE EPIPLOICA, RESECTION :
INFARCTED EPIPLOICA.

PERIHILAR RENAL LYMPH NODE, RESECTION:
FOLLICULAR HYPERPLASIA.

LEFT KIDNEY, RADICAL NEPHRECTOMY:
PAPILLARY RENAL CELL CARCINOMA, FUHRMAN GRADE 3/4.
ONE LYMPH NODE NEGATIVE FOR TUMOR.
ADRENAL GLAND NEGATIVE FOR TUMOR.

Intradepartmental Consult

Comment

Positive and negative controls react satisfactorily.

FDA required disclaimer: These tests were developed and their performance characteristics determined by [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

[REDACTED] - required information for predictive/prognostic markers: 1. Type of specimen fixation and detection system: Tissue is fixed in 10% formalin. Indirect biotin-free detection kit is used. 2. Clones used: ER (clone [REDACTED] Novocastra; PR (clone [REDACTED] DakoCytomation; CD117 (polyclonal, DakoCytomation); HER2 (clone [REDACTED] Ventana, FDA approved); Ki-67 (clone [REDACTED] Cell Marque) p53 (clone [REDACTED] Novocastra), MSH6 (clone [REDACTED] Biocare), MSH2 (CellMarque clone [REDACTED]), MLH1 (Cell Marque clone [REDACTED]), PMS2 (clone [REDACTED] Cell Marque). 3. Criteria for positive results: ER and PR: $\geq 1\%$ of tumor cells with nuclear staining; HER2: $>30\%$ of cells show complete membrane staining; p53: $\geq 10\%$ of tumor cells with nuclear staining; MMR Proteins: complete absence of tumor nuclear staining.

CPT Code(s)

A: 88305

B: 88305

C: 88331, 88307, 88342, 88342, 88342, 88342, 88342, 88342, 88342, 88342, 88342, IHC S/O(3)

Source: NCI Genomic Data Commons file 33ed75c2-97ae-4921-8293-f3e65fb9ddc5 (TCGA-A4-7915.876CCD1A-95B5-4C2B-B6E4-CED1BD1A58E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).